Surgical pathology report (de-identified scan), TCGA case TCGA-CZ-4858, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Harvard, specimen TCGA-CZ-4858-01A (Primary Tumor).

[page 1 of 3]
Resident:
Pathologi

TCGA-CZ-4858

PATHOLOGIC DIAGNOSIS:

LEFT KIDNEY, NEPHRECTOMY:
RENAL CELL CARCINOMA, clear cell type (7.8 cm), Fuhrman nuclear grade IV/IV with extensive tumor necrosis, is present in the lower pole.

No lymphovascular invasion is seen.

The carcinoma is confined to the kidney.

The ureteral, vascular, and soft tissue margins are not involved.

Blood vessel with organizing thrombus.

Adrenal gland with no tumor seen.

Note: The normal parenchyma will be evaluated and reported in an addendum.

This carcinoma would be classified as AJCC (6th edition) T2 NX MX.

CLINICAL DATA:

History: with left renal mass.

Operation: Left radical, hand assisted laparoscopic nephrectomy.

Operative Findings: Not provided.

Clinical Diagnosis: Left renal mass.

TISSUE SUBMITTED:

A/1. Not specified.

GROSS DESCRIPTION:

The specimen is received fresh, labeled with the patient's name, unit number, and "#1. Left kidney", and consists of a 901 gm radical nephrectomy specimen (20.1 x 10.8 x 10.4 cm), to include left kidney (18.9 x 8.5 x 6.0 cm), perinephric fat (maximally 4.5 cm in thickness), and a small amount of disrupted-appearing adrenal tissue (2.4 x 1.4 cm). An 8.2 cm ureter (diameter 0.3 cm), 2.0 cm renal artery (diameter 0.4 cm), 1.3 cm renal vein (maximum diameter 1.8 cm) are identified at the hilum. The specimen is inked black and bivalved to reveal a 7.8 x 6.4 x 5.9 cm circumscribed tan/yellow, multifocally hemorrhagic mass with focal central necrosis (< 10% of mass) in the lower pole. The mass abuts but does not grossly invade the renal vein and is 2.0 cm from the renal vein margin. Tumor expands and compresses the renal cortex, focally abutting the renal capsule, however, there is no clear gross invasion through the renal capsule into the surrounding adipose tissue. The closest black inked surgical margin is 0.8 cm. The remaining renal parenchyma is remarkable for a single 0.3 cm tan/yellow nodule in a vessel in the mid/upper pole, remote from (> 3.0 cm) the tumor mass. The remaining renal parenchyma is grossly unremarkable. An adrenal gland is questionably complete. The specimen was received focally disrupted (mid/superior pole); the 8.5 x 0.5 cm superficial defect in the adipose tissue has been inked blue per tissue bank resident. Representative tumor has been submitted to the tissue bank, four sections are submitted for quick-fixation, which correspond to four sections of tumor sent to the tissue bank (T1-T4). In addition, representative tumor has been sent for EM and cytogenetics. Representative normal cortex is submitted for EM, IF, and tissue bank. Gross photographs have been taken.

[page 2 of 3]
Micro A1: Ureteral, vascular margins, multi frags, [REDACTED]
Micro A2: T1 quick-fix section, 1 frag, [REDACTED]
Micro A3: T2 quick-fix section, 1 frag, [REDACTED]
Micro A4: T3 quick-fix section, 1 frag, [REDACTED]
Micro A5: T5 quick-fix section, 1 frag, [REDACTED]
Micro A6: Tumor and adjacent renal vein, 1 frag, [REDACTED]
Micro A7: Tumor and renal capsule, tumor and inked margin, 2 frags, [REDACTED]
Micro A8: Tumor and uninvolved renal parenchyma, 1 frag, [REDACTED]
Micro A9: Possible satellite nodule, 1 frag, [REDACTED]
Micro A10: Uninvolved kidney, adrenal gland, 2 frags, [REDACTED]

[REDACTED]

By his/her signature below, the senior physician certifies that he/she personally conducted a microscopic examination ("gross only" exam if so stated) of the described specimen(s) and rendered or confirmed the diagnosis(es) related thereto.

[REDACTED]

ADDENDUM

RENAL PATHOLOGY EVALUATION OF NON-NEOPLASTIC RENAL PARENCHYMA [REDACTED] :

GLOMERULI, TUBULES AND INTERSTITIUM WITH NO SIGNIFICANT PATHOLOGIC CHANGES

ARTERIAL SCLEROSIS, FOCALLY MODERATE

MICROSCOPIC DESCRIPTION

The sample consists of kidney cortex and medulla. There are up to one hundred and eighty five (185) glomeruli present in the sample submitted for light microscopy. None of the glomeruli are globally obsolescent (sclerosed). The preserved glomeruli show normal cellularity and reveal no significant pathological changes. On PAS stain, the mesangium appears mildly thickened. The glomerular basement membranes appear of normal thickness as seen on Jones silver methenamine. Tubules are well preserved. The interstitium shows no fibrosis or active inflammation. Less than 5% of the sample shows tubular atrophy and interstitial fibrosis, as evidenced on the trichrome stains (AFOG). Arteries exhibit focally moderate subintimal sclerosis and arterioles are unremarkable.

GROSS DESCRIPTION:

Micro A11: uninvolved kidney, 1 fragment, [REDACTED]

[REDACTED]

[page 3 of 3]
Accession Number: [REDACTED]
Type: Cytogenetics
CASE [REDACTED]
PATIENT: [REDACTED]
Cytogeneticist
[REDACTED]

Report Status: Final

KARYOTYPE: see interpretation

METAPHASES COUNTED: 0 ANALYZED: 0 SCORED: 0 BANDING: GTG

INTERPRETATION:

Cell cultures were attempted but unsuccessful, and the cytogenetic analysis could not be performed.

INDICATION FOR TEST:

? RCC

[REDACTED]

Source: NCI Genomic Data Commons file 8b9cb04e-063e-4f70-ad07-ad1b95de06e7 (TCGA-CZ-4858.5D3A8EDA-816D-4B0F-A6A6-C70B2BABF55C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).